Surgical pathology report (de-identified scan), TCGA case TCGA-CD-5801, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site ILSBio, specimen TCGA-CD-5801-01A (Primary Tumor).

[page 1 of 6]
I personally informed this patient that a specimen(s) would be collected to be used for research purposes. I reviewed the [REDACTED] **RESEARCH SUBJECT INFORMATION AND CONSENT FORM** with the patient and answered any questions the patient had. The patient then signed the consent form as a free and voluntary act. A copy of this informed consent document will be retained at our institution.

Clinical Information

HISTORY OF PRESENT ILLNESS

Chief Complaints:

Abdominal pain.

Symptoms:

patient has persistent cramp-like pain in upper abdomen area, loss of appetite and indigestion.

Clinical Findings:

Abdomen is soft, no tumor or peripheral lymph node was found.

Performance Scale (Karnofsky Score):

- ☐ 100 Asymptomatic ☐ 80-90 Symptomatic but Fully Ambulatory ☐ 60-70 Symptomatic, in bed less than 50% of day
☐ 40-50 Symptomatic, in bed more than 50% of day, but not bed ridden ☐ 20-30 Bed Ridden

CURRENT MEDICATIONS

Drug	Dose	Route	Frequency	Date (mm/dd/yyyy)
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 2 of 6]
PAST MEDICAL HISTORY			
Diagnosis/Disease/Disorder/Injury	Diagnosis Date	Treatment	Status
High blood pressure			

SOCIAL HISTORY				
Occupation:		Environmental Hazards:		
Smoking History				
Current Status	TYPE	Packs/day	Duration	When Quit
☒ YES ☐ NO	N/A	N/A	(yrs)	(yr)
Alcohol Consumption				
Current Status	TYPE	Drinks/day	Duration	When Quit
☒ YES ☐ NO	N/A	N/A	(yrs)	(yr)
Drug Use				
Current Status	TYPE	Frequency	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)

FAMILY MEDICAL HISTORY		
Relative	Diagnosis	Age of Diagnosis
Nobody has cancer.		

LAB DATA						
Test	Result	Date		Test	Result	Date
				CEA	☐ Negative ☐ Positive: _____	
				CA 15-3	☐ Negative ☐ Positive: _____	
Hep C	☐ Negative ☐ Positive: _____			CA 19-9	☐ Negative ☐ Positive: _____	
AFP	☐ Negative ☐ Positive: _____			PSA	☐ Negative ☐ Positive: _____	
Other:	☐ Negative ☐ Positive: _____			Other:	☐ Negative ☐ Positive: _____	
B/T Cell Markers:						

[page 3 of 6]
DIAGNOSTIC STUDIES		
Study	Results	Date
Ultrasound	/ Normal Tumor is stomach Tumor is antrum and body of stomach Adenocarcinoma	
X-Ray		
CT		
Endoscopy		
MRI		
Biopsy		

CLINICAL DIAGNOSIS		
Preoperative Clinical Diagnosis		
Stomach Cancer		
Location of Suspected Involved Lymph Nodes	Location of Suspected Distant Metastasis	
Perigastric lymph nodes	NO	
Clinical Staging		Date of Diagnosis
T4 N2 M0 Stage: IV		

Treatment Information

SURGICAL TREATMENT			
Procedure		Date	
Total gastrectomy			
Primary Tumor			
Organ	Detailed Location	Size	
Stomach	Body and antrum	4.5x	x cm
Extension of Tumor			
Serosa			
Lymph Nodes			
Description	Location of Lymph Nodes	# of Lymph Nodes	
Palpable, Non-Dissected Lymph Nodes	Perigastric	5	
Dissected Lymph Nodes			
Distant Metastasis			
Organ	Detailed Location	Size	
NO			
Surgical Staging			
T3 N1 M0 Stage: IIIA			

NEOADJUVANT THERAPY (Chemo, Radiation, Immuno, Hormonal, or Molecular)				
Drug/Treatment	Dose	Route	Frequency	Date (mm/dd/yyyy)
NO				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 4 of 6]
Pathology Form

Specimen Information

SPECIMEN TYPE (# of samples provided)

Frozen		Paraffin Block		Blood/Serum/Plasma		Slide	
Diseased	Normal	Diseased	Normal	Diseased	Normal	Diseased	Normal
X	✓	✓	✓			✓	X
Time to LN2		Time to Formalin		Time to LN2			
10 min		10 min		60 min			

PATHOLOGICAL DESCRIPTION

Primary Tumor

Organ	Size	Extension of Tumor	Distance to NAT
Stomach	4.5 x cm	Serosa	2 cm

Lymph Nodes

Location	# Examined	# Metastasized
Perigastric	5	5

Distant Metastasis

Organ	Detailed Location	Size
NO		

Pathological Staging

pT₃ N₁ M₀ Stage: IIIA

Notes:

[page 5 of 6]
Microscopic Description

Histological Pattern											
Cell Distribution			+	-	Structural Pattern			+	-		
Diffuse			+		Streaming						
Mosaic					Storiform						
Necrosis					Fibrosis						
Lymphocytic Infiltration					Palisading						
Vascular Invasion					Cystic Degeneration						
Clusterized			+		Bleeding						
Alveolar Formation					Myxoid Change						
Indian File					Psammoma/Calcification						

Cellular Differentiation															
Squamous		+	-	Adenomatous		+	-	Sarcomatous		+	-	Lymphomatous		+	-
Squamoid Cell				Glandular cell		+		Round Cell				Large Cell			
Spindle Cell				Cell Stratification				Fibroblast				Small Cell			
Keratin				Secretion				Osteoblast				RS Cell/RS Like			
Desmosome				Intracyt. Vacuole				Lipoblast				Inflam. Cell			
Pearl				Gland formation				Myoblast				Plasma Cell			

Cellular Differentiation: Well Moderate ~~✓~~ Poor

Nuclear Appearance				
Nuclear Atypia:	0	I	II	III
Aniso Nucleosis				+
Hyperchromatism				+
Nucleolar Prominent			+	
Multinucleated Giant Cell				
Mitotic Activity			+	
Nuclear Grade:				+

IHC Data			
Marker	Result	Value	Date
ER	☐ Negative ☐ Positive		
PR	☐ Negative ☐ Positive		
Her-2/neu	☐ Negative ☐ Positive		
B-Cell Marker	☐ Negative ☐ Positive		
T-Cell Marker	☐ Negative ☐ Positive		
Other:	☐ Negative ☐ Positive		
Other:	☐ Negative ☐ Positive		

Final Pathology Report

Histological Diagnosis: poorly differentiated adenocarcinoma Grade: III

[page 6 of 6]
Microscopic Appearance:

1. Histological pattern:

CELL DISTRIBUTION			STRUCTURAL PATTERN		
	+	-		+	-
Diffuse		☒	Streaming		
Mosaic	☒		Storiform		
Necrosis		☒	Fibrosis		
Lymphocytic Infiltration		☒	Palisading		
Vascular Invasion	☒		Cystic Degeneration		
Clusterized	☒		Bleeding		
Alveolar Formation		☒	Myxoid Change		
Indian File		☒	Psammoma/Calcification		

2. Cellular features:

	+	-		+	-		+	-		+	-
Squamous			Adenomatous			Sarcomatous			Lymphomatous		
Squamoid Cell			Glandular cell	☒		Round Cell			Large Cell		
Spindle Cell			Cell Stratification	☒		Fibroblast			Small Cell		
Keratin			Secretion	☒		Osteoblast			RS Cell/RS Like		
Desmosome			Intracyt. Vacuole	☒		Lipoblast			Inflam. Cell		
Pearl			Gland formation	☒		Myoblast			Plasma Cell		
Otherwise Specified: 50% D2 20% D3 60% D4 60%											

2. Cellular Differentiation:

Well	Moderately	Poor
		☒

3. Nuclear Atypia:

Nuclear Appearance	0	I	II	III
Aniso Nucleosis				☒
Hyperchromatism			☒	
Nucleolar Prominent				☒
Multinucleated Giant Cell			☒	
Mitotic Activity				☒
Nuclear Grade				☒

Histological Diagnosis: Adenocarcinoma, G-3

Comments: U, M = carcinoma metastatic to LN

Source: NCI Genomic Data Commons file 44b59b77-9252-4046-996b-84e5da1789a6 (TCGA-CD-5801.C1508C91-7C9C-45AF-B741-5304F8C34ACB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).